Somatic mutation profile of tumor specimen TCGA-FA-A82F-01A (aliquot TCGA-FA-A82F-01A-11D-A382-10) from TCGA case TCGA-FA-A82F, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Diffuse large B-cell lymphoma, NOS; Tissue or organ of origin: Small intestine, NOS; Age at diagnosis: 48.8 years (17,819 days).
Specimen TCGA-FA-A82F-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ac35caa6-9543-4cc4-9ff5-64a09163a4a8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FA-A82F-10A (Blood Derived Normal), aliquot TCGA-FA-A82F-10A-01D-A385-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d81dcc7f-58a0-4cb4-90e8-450dbfc867d8

The open-access MAF lists 165 somatic variants for this specimen: 126 protein-altering or splice-affecting, 34 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 107, Silent 34, Nonsense Mutation 10, Frame Shift Del 4, 3'UTR 2, Splice Region 2, Splice Site 2, RNA 1, 5'Flank 1, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIM1 | c.237G>T p.E79D | Missense Mutation (SNP) | VAF 18/74 reads (24%) | hotspot (GDC flag); SIFT tolerated (0.19); PolyPhen benign (0.031); catalogued as COSV100998754, COSV65164441, COSV65164484; called by muse, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 27/52 reads (52%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAT1 | c.425G>A p.C142Y | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100329286; called by muse, mutect2, varscan2
- AMPD3 | c.1751G>A p.R584Q (on ENST00000396553 / NM_001025389.2; = p.R593Q on NM_000480.3) | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777313112, COSV101158237; called by muse, mutect2, varscan2
- ANKRD17 | c.2620C>T p.R874* | Nonsense Mutation (SNP) | VAF 127/439 reads (29%) | catalogued as COSV100429821; called by muse, mutect2, varscan2
- ANKRD50 | c.133A>C p.N45H | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as COSV101539027; called by muse, mutect2, varscan2
- AP1M1 | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs940245777, COSV99358601; called by muse, mutect2, varscan2
- ARAP2 | c.4746T>C p.S1582= | Splice Region (SNP) | VAF 8/55 reads (15%) | catalogued as COSV100395143; called by muse, mutect2, varscan2
- ARHGAP20 | c.102G>C p.K34N | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as COSV52813084, COSV99505051; called by muse, mutect2, varscan2
- ASTN2 | c.562G>A p.A188T | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as rs774014251, COSV100529779; called by muse, mutect2, varscan2
- ASXL3 | c.577C>A p.Q193K | Missense Mutation (SNP) | VAF 30/147 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); catalogued as COSV99326139; called by muse, mutect2, varscan2
- ATP1A4 | c.2506G>A p.D836N | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as rs752142002, COSV63626009; called by muse, mutect2, varscan2
- CCDC17 | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.843); catalogued as rs967961523, COSV99322642; called by muse, mutect2, varscan2
- CCDC50 | c.482G>T p.G161V | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.069); catalogued as COSV101165346; called by muse, mutect2, varscan2
- CDH4 | c.784G>A p.D262N | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.083); catalogued as COSV100848540, COSV100849420; called by muse, mutect2, varscan2
- CDK14 | c.454G>C p.G152R (on ENST00000380050 / NM_001287135.2; = p.G134R on NM_012395.3) | Missense Mutation (SNP) | VAF 49/220 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99726555; called by muse, mutect2, varscan2
- CNTN1 | c.337T>A p.Y113N | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.266); catalogued as COSV100751828; called by muse, mutect2, varscan2
- CSMD1 | c.1395C>A p.D465E (on ENST00000520002; = p.D464E on NM_033225.6) | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV101224101, COSV68249274; called by muse, mutect2, varscan2
- DES | c.29G>A p.R10H | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.392); catalogued as rs757839952, COSV100900542; called by muse, mutect2, varscan2
- DNAH11 | c.10328A>T p.Q3443L | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV100180348; called by muse, mutect2, varscan2
- EGFL7 | c.752A>C p.D251A | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100452044; called by muse, mutect2, varscan2
- EIF3E | c.1282C>T p.Q428* | Nonsense Mutation (SNP) | VAF 39/108 reads (36%) | catalogued as COSV55201129; called by muse, mutect2, varscan2
- ENO1 | c.334C>G p.L112V | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.877); catalogued as COSV99318970; called by muse, mutect2, varscan2
- EPHX1 | c.110G>T p.G37V | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99689159; called by muse, mutect2, varscan2
- ESRRG | c.1193C>A p.A398E | Missense Mutation (SNP) | VAF 48/163 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100753692; called by muse, mutect2, varscan2
- EXOC3L4 | c.1217C>T p.A406V | Missense Mutation (SNP) | VAF 28/47 reads (60%) | SIFT tolerated (0.16); PolyPhen benign (0.086); catalogued as COSV101197698; called by muse, mutect2, varscan2
- EYS | c.775del p.Q259Sfs*80 | Frame Shift Del (DEL) | VAF 174/566 reads (31%) | catalogued as COSV60976531; called by mutect2, varscan2
- FAAP24 | c.337G>A p.G113R | Missense Mutation (SNP) | VAF 26/169 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99578149; called by muse, mutect2, varscan2
- FANCE | c.169C>G p.P57A | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.5); PolyPhen benign (0.103); catalogued as COSV100003541; called by muse, mutect2
- FAT4 | c.5534T>C p.V1845A | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.878); catalogued as rs1480817780, COSV100629771; called by muse, mutect2, varscan2
- FKBP6 | c.229T>G p.F77V | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.03); catalogued as COSV99334254; called by muse, mutect2, varscan2
- GFPT1 | c.1420C>T p.R474W (on ENST00000357308 / NM_001244710.2; = p.R456W on NM_002056.4) | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.161); catalogued as rs1463589309, COSV100622970; called by muse, mutect2, varscan2
- GRHPR | c.133C>G p.L45V | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV100547078; called by muse, mutect2, varscan2
- H1-2 | c.178G>C p.A60P | Missense Mutation (SNP) | VAF 56/155 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.714); catalogued as rs1371538329, COSV100642323; called by muse, mutect2, varscan2
- HEPHL1 | c.2054C>G p.T685R | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as COSV100244251, COSV59892205; called by muse, mutect2
- HGH1 | c.604C>T p.Q202* | Nonsense Mutation (SNP) | VAF 6/34 reads (18%) | catalogued as COSV61690887; called by muse, mutect2
- HLA-B | c.343+1G>A p.X115_splice | Splice Site (SNP) | VAF 8/38 reads (21%) | catalogued as rs1168937188, COSV69520345, COSV69521733; called by muse, mutect2
- HNF4G | c.264A>C p.R88S (on ENST00000354370 / NM_001330561.2; = p.R135S on NM_004133.5) | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.411); catalogued as COSV100584915; called by muse, mutect2, varscan2
- HNRNPD | c.149G>A p.G50E | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated, low confidence (0.37); PolyPhen probably damaging (0.982); catalogued as COSV100003057; called by muse, mutect2, varscan2
- HOXC11 | c.667A>T p.K223* | Nonsense Mutation (SNP) | VAF 7/20 reads (35%) | catalogued as COSV99678497; called by muse, mutect2, varscan2
- HSF2 | c.644A>C p.H215P | Missense Mutation (SNP) | VAF 42/78 reads (54%) | SIFT tolerated (0.25); PolyPhen benign (0.071); catalogued as COSV100869713; called by muse, varscan2
- HSPG2 | c.6146G>A p.S2049N | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV101021085; called by muse, varscan2
- HUNK | c.1717G>A p.V573M | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs769352625, COSV99528855; called by muse, mutect2, varscan2
- IDO2 | c.1040A>T p.H347L (on ENST00000389060; = p.H360L on NM_194294.2) | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100584930; called by muse, mutect2
- IGHA2 | c.506G>A p.C169Y | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs782294710; called by muse, mutect2, varscan2
- IMPG1 | c.1193C>A p.S398Y | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.188); catalogued as COSV100886595; called by muse, mutect2, varscan2
- INPP4B | c.992G>A p.S331N | Missense Mutation (SNP) | VAF 26/196 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.019); catalogued as rs1402313451, COSV99526189; called by muse, mutect2, varscan2
- INPP4B | c.423+1G>A p.X141_splice | Splice Site (SNP) | VAF 40/110 reads (36%) | catalogued as COSV99526192; called by muse, mutect2, varscan2
- JMJD6 | c.1196G>A p.R399H | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.513); catalogued as rs769402176, COSV58300838; called by muse, mutect2, varscan2
- KDM6A | c.3310A>C p.T1104P | Missense Mutation (SNP) | VAF 105/184 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.623); catalogued as COSV65044817; called by muse, mutect2, varscan2
- KIF25 | c.577G>A p.A193T | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.046); catalogued as rs148907230; called by muse, mutect2, varscan2
- KIF6 | c.812A>C p.K271T | Missense Mutation (SNP) | VAF 68/196 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV99760269; called by muse, mutect2, varscan2
- KLHL36 | c.743G>A p.R248H | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.8); catalogued as rs773009543, COSV99257023; called by mutect2, varscan2
- KMT2A | c.6443C>T p.P2148L | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs781897465, COSV100629623; called by muse, mutect2, varscan2
- KMT2D | c.11635_11636del p.L3880Dfs*131 | Frame Shift Del (DEL) | VAF 16/66 reads (24%) | catalogued as rs1555188561; called by pindel, varscan2
- LAMA1 | c.749A>G p.D250G | Missense Mutation (SNP) | VAF 66/140 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101057429; called by muse, mutect2, varscan2
- LATS2 | c.1738G>A p.V580I | Missense Mutation (SNP) | VAF 91/357 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as COSV101231572; called by muse, mutect2, varscan2
- LONRF2 | c.1219G>A p.V407M | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs562655594, COSV101111037, COSV66539431; called by muse, mutect2, varscan2
- LRP1B | c.5354T>C p.I1785T | Missense Mutation (SNP) | VAF 25/200 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.214); catalogued as COSV101256978; called by muse, mutect2, varscan2
- LRRTM1 | c.1448T>C p.M483T | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs1558983438, COSV99702985; called by muse, mutect2, varscan2
- LSAMP | c.200G>A p.R67H | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs577289191, COSV61277398; called by muse, mutect2, varscan2
- MAB21L2 | c.587G>A p.G196D | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.186); catalogued as COSV100462373; called by muse, mutect2, varscan2
- MBL2 | c.736T>G p.F246V | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV100906391; called by muse, mutect2, varscan2
- MED29 | c.406C>T p.Q136* (on ENST00000615911; = p.Q115* on NM_017592.4) | Nonsense Mutation (SNP) | VAF 11/51 reads (22%) | catalogued as COSV99655987; called by muse, mutect2, varscan2
- MGAT5B | c.1231G>A p.G411S | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1261011121, COSV100048774; called by muse, mutect2, varscan2
- MITF | c.584T>G p.F195C (on ENST00000448226 / NM_006722.3; = p.F89C on NM_000248.4) | Missense Mutation (SNP) | VAF 52/192 reads (27%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.634); catalogued as COSV100097322; called by muse, mutect2, varscan2
- MMP2 | c.475T>G p.F159V | Missense Mutation (SNP) | VAF 52/115 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.473); catalogued as COSV99528174; called by muse, mutect2, varscan2
- MMRN1 | c.1938G>C p.M646I | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV99307636; called by muse, mutect2, varscan2
- MON2 | c.2372C>G p.S791C | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.634); catalogued as COSV99743310; called by muse, mutect2, varscan2
- MPDZ | c.661G>T p.A221S | Missense Mutation (SNP) | VAF 45/144 reads (31%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.953); catalogued as COSV100064221; called by muse, mutect2, varscan2
- MTUS1 | c.1610C>A p.T537N | Missense Mutation (SNP) | VAF 56/187 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as COSV100029897; called by muse, mutect2, varscan2
- MUC16 | c.43435C>T p.R14479C | Missense Mutation (SNP) | VAF 37/149 reads (25%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs572151289, COSV101110105, COSV66693402; called by muse, mutect2, varscan2
- MUC5B | c.10631C>T p.T3544I | Missense Mutation (SNP) | VAF 41/159 reads (26%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.72); catalogued as rs1411290183, COSV101500658; called by muse, mutect2, varscan2
- NFKBIA | c.154A>T p.I52F | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV99395307; called by muse, mutect2, varscan2
- NINL | c.1751A>T p.H584L | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.037); catalogued as COSV99625990; called by muse, mutect2, varscan2
- OR10G8 | c.385C>A p.L129I | Missense Mutation (SNP) | VAF 76/298 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101461867; called by muse, mutect2, varscan2
- OR52M1 | c.362C>G p.A121G | Missense Mutation (SNP) | VAF 63/240 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV100798610, COSV64172790; called by muse, mutect2, varscan2
- OR5T2 | c.381G>T p.K127N | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as COSV100507045; called by muse, mutect2, varscan2
- OR6C75 | c.774T>G p.I258M | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.17); catalogued as COSV100595424; called by muse, mutect2, varscan2
- OSMR | c.654T>G p.S218R | Missense Mutation (SNP) | VAF 55/718 reads (8%) | SIFT tolerated (0.54); PolyPhen benign (0.057); catalogued as COSV99953592; called by muse, mutect2
- P2RX5 | c.129C>A p.Y43* | Nonsense Mutation (SNP) | VAF 30/56 reads (54%) | catalogued as COSV99835945; called by muse, varscan2
- PACC1 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.113); catalogued as rs1006449616, COSV99801488; called by muse, mutect2, varscan2
- PCDHA1 | c.1775C>T p.A592V | Missense Mutation (SNP) | VAF 42/124 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.104); catalogued as rs190769137, COSV100974436; called by muse, mutect2, varscan2
- PCLO | c.7024C>A p.H2342N | Missense Mutation (SNP) | VAF 21/186 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.009); catalogued as COSV100436557, COSV61616335; called by muse, mutect2, varscan2
- PIM1 | c.427C>G p.L143V | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT tolerated (0.5); PolyPhen benign (0.107); catalogued as COSV65165461, COSV65165620, COSV65166304; called by muse, mutect2, varscan2
- PLCB1 | c.1072C>T p.R358C | Missense Mutation (SNP) | VAF 110/280 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100571864; called by muse, varscan2
- PLXNB3 | c.3208C>A p.P1070T | Missense Mutation (SNP) | VAF 28/44 reads (64%) | SIFT tolerated (0.36); PolyPhen benign (0.079); catalogued as COSV100737798; called by muse, mutect2, varscan2
- POU2F2 | c.310C>T p.Q104* | Nonsense Mutation (SNP) | VAF 23/69 reads (33%) | catalogued as COSV100657481; called by muse, mutect2, varscan2
- PPFIA4 | c.382T>C p.S128P | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99830375; called by muse, mutect2, varscan2
- PPM1H | c.86G>A p.S29N | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs754964484, COSV99956356; called by muse, mutect2, varscan2
- PPP4R3A | c.1567C>T p.H523Y (on ENST00000554943 / NM_001366432.1; = p.H510Y on NM_001284280.1) | Missense Mutation (SNP) | VAF 44/121 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100466394; called by muse, mutect2, varscan2
- PRDM15 | c.1396A>G p.K466E | Missense Mutation (SNP) | VAF 68/183 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); catalogued as COSV99520800; called by muse, varscan2
- PRICKLE2 | c.382C>T p.R128* (on ENST00000295902; = p.R72* on NM_198859.4) | Nonsense Mutation (SNP) | VAF 44/127 reads (35%) | catalogued as COSV55769402; called by muse, mutect2, varscan2
- PRKCD | c.1393C>T p.H465Y | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100388045; called by muse, mutect2, varscan2
- PTPRG | c.4222C>T p.L1408F | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99876562; called by muse, mutect2, varscan2
- RASEF | c.2170A>T p.T724S | Missense Mutation (SNP) | VAF 51/203 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100907040; called by muse, mutect2, varscan2
- RCVRN | c.418C>A p.L140I | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as COSV99874330; called by muse, mutect2, varscan2
- RMND5B | c.79C>T p.R27W | Missense Mutation (SNP) | VAF 42/130 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.28); catalogued as rs978627661, COSV100523326; called by muse, mutect2, varscan2
- ROBO1 | c.2008C>A p.Q670K | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV101459160; called by muse, mutect2, varscan2
- RUBCN | c.2023G>A p.G675R | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.479); catalogued as rs749861053, COSV56365143, COSV99584882; called by muse, mutect2, varscan2
- SEL1L3 | c.2816C>T p.S939F | Missense Mutation (SNP) | VAF 60/222 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99341063; called by muse, varscan2
- SH3BP4 | c.1868G>A p.R623K | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.97); catalogued as COSV100749282; called by muse, mutect2, varscan2
- SIN3A | c.1802A>G p.K601R | Missense Mutation (SNP) | VAF 11/115 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0.405); catalogued as rs985300880, COSV100845217; called by muse, mutect2, varscan2
- SLC26A3 | c.2255G>A p.R752H | Missense Mutation (SNP) | VAF 38/148 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.031); catalogued as rs765288477, COSV60641616; called by muse, mutect2, varscan2
- SLC4A4 | c.1744C>T p.R582C (on ENST00000264485 / NM_001098484.3; = p.R538C on NM_003759.4) | Missense Mutation (SNP) | VAF 42/154 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99141612; called by muse, mutect2, varscan2
- SOHLH2 | c.1009A>C p.S337R | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.526); catalogued as COSV101157981; called by muse, mutect2, varscan2
- SORL1 | c.1693A>C p.T565P | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV99495136; called by muse, mutect2, varscan2
- SPATA31E1 | c.2651G>T p.R884L | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs778800039, COSV100350727, COSV100350931; called by muse, mutect2, varscan2
- STK36 | c.148C>T p.R50* | Nonsense Mutation (SNP) | VAF 39/93 reads (42%) | catalogued as rs1337379321, COSV55305988; called by muse, mutect2, varscan2
- TAFA1 | c.68G>T p.C23F | Missense Mutation (SNP) | VAF 58/181 reads (32%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.831); catalogued as COSV101524524; called by muse, mutect2, varscan2
- THSD7A | c.4765C>T p.R1589W | Missense Mutation (SNP) | VAF 106/277 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.821); catalogued as rs752652034, COSV101349199; called by muse, mutect2, varscan2
- TLN1 | c.1171C>T p.L391F | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59209020; called by muse, mutect2, varscan2
- TLR4 | c.682C>A p.L228I (on ENST00000355622 / NM_138554.5; = p.L188I on NM_003266.4) | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100790685; called by muse, mutect2, varscan2
- TMEFF2 | c.152C>T p.P51L | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.636); catalogued as COSV99772220; called by muse, mutect2, varscan2
- TNKS | c.1727T>G p.V576G | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.589); catalogued as COSV100127677; called by muse, mutect2
- TNPO1 | c.863G>A p.W288* | Nonsense Mutation (SNP) | VAF 36/111 reads (32%) | catalogued as COSV100473847; called by muse, mutect2, varscan2
- TRIM11 | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV99488859; called by muse, mutect2, varscan2
- TSHZ1 | c.1117G>C p.E373Q (on ENST00000580243 / NM_001308210.2; = p.E328Q on NM_005786.6) | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0.029); catalogued as COSV100433901; called by muse, mutect2, varscan2
- TUSC2 | c.29G>A p.G10D | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs1406412075, COSV99222854; called by mutect2, varscan2
- UNC5D | c.2317G>A p.V773I | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV99778009; called by muse, mutect2, varscan2
- USP20 | c.1392G>A p.R464= | Splice Region (SNP) | VAF 5/49 reads (10%) | catalogued as COSV100204668; called by muse, mutect2, varscan2
- ZMYM4 | c.4490G>A p.R1497H | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs142484548; called by muse, mutect2, varscan2
- ZNF248 | c.1061A>C p.Y354S | Missense Mutation (SNP) | VAF 55/266 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.056); catalogued as COSV100627700; called by muse, varscan2
- ATP2A3 | c.2023_2028delinsGTGGA p.C675Vfs*26 | Frame Shift Del (DEL) | VAF 32/51 reads (63%) | called by pindel, varscan2*
- BTG2 | c.152_153del p.K51Tfs*57 | Frame Shift Del (DEL) | VAF 10/50 reads (20%) | called by mutect2, pindel*, varscan2
- PANK2 | c.1125dup p.P376Tfs*3 (on ENST00000316562 / NM_153638.3; = p.P85Tfs*3 on NM_024960.6 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 51/150 reads (34%) | called by mutect2, pindel, varscan2
- ABCF1 | c.1563C>T p.L521= (on ENST00000326195 / NM_001025091.2; = p.L483= on NM_001090.3) | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as rs928838252, COSV100401002; called by muse, mutect2, varscan2
- ACE | c.3426G>A p.L1142= | Silent (SNP) | VAF 54/140 reads (39%) | catalogued as rs1568048580, COSV99327588; called by muse, mutect2, varscan2
- ADAMTS13 | c.2700G>A p.A900= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as rs782742222, COSV63023473; called by muse, mutect2
- APOL5 | c.459C>T p.I153= | Silent (SNP) | VAF 25/103 reads (24%) | catalogued as COSV50766543; called by muse, mutect2, varscan2
- ARHGAP28 | c.1236A>C p.S412= (on ENST00000383472 / NM_001366230.1; = p.S253= on NM_001010000.3) | Silent (SNP) | VAF 18/135 reads (13%) | catalogued as COSV99151298; called by muse, mutect2, varscan2
- ARSL | c.294C>T p.Y98= | Silent (SNP) | VAF 51/110 reads (46%) | catalogued as rs1382183104, COSV66965516; called by muse, mutect2, varscan2
- BRINP3 | c.66A>G p.A22= | Silent (SNP) | VAF 29/89 reads (33%) | catalogued as rs190123682, COSV100819250; called by muse, mutect2, varscan2
- BTG1 | c.109C>T p.L37= | Silent (SNP) | VAF 34/110 reads (31%) | catalogued as rs369374957, COSV55458204, COSV55458724; called by muse, varscan2
- DTX1 | c.150C>T p.N50= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as COSV57500419; called by muse, mutect2, varscan2
- EPHB4 | c.504G>A p.P168= | Silent (SNP) | VAF 17/82 reads (21%) | catalogued as rs532613401, COSV100639619; called by muse, mutect2, varscan2
- H2BC17 | c.216G>A p.E72= | Silent (SNP) | VAF 37/136 reads (27%) | catalogued as COSV100377692; called by muse, mutect2, varscan2
- HRH1 | c.1299C>A p.I433= | Silent (SNP) | VAF 25/92 reads (27%) | catalogued as rs1298069718, COSV101229100, COSV67955777; called by muse, mutect2, varscan2
- IGHA2 | c.12C>G p.T4= | Silent (SNP) | VAF 6/19 reads (32%) | called by muse, mutect2, varscan2
- KLHL14 | c.447G>A p.L149= | Silent (SNP) | VAF 75/146 reads (51%) | catalogued as rs1468916040, COSV100809225; called by muse, mutect2, varscan2
- KRTAP5-5 | c.309G>A p.G103= | Silent (SNP) | VAF 18/64 reads (28%) | catalogued as COSV101294204; called by muse, mutect2, varscan2
- MPPED1 | c.576C>A p.I192= | Silent (SNP) | VAF 23/78 reads (29%) | catalogued as COSV101342272; called by muse, mutect2, varscan2
- NACC2 | c.1629C>T p.A543= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as rs935145376, COSV99508513; called by muse, mutect2, varscan2
- NID1 | c.2706C>T p.D902= | Silent (SNP) | VAF 31/82 reads (38%) | catalogued as rs1264100851, COSV99938143; called by muse, mutect2, varscan2
- NMRAL1 | c.336C>T p.S112= | Silent (SNP) | VAF 18/39 reads (46%) | catalogued as rs763001414, COSV52059711; called by muse, mutect2, varscan2
- NTSR1 | c.723C>T p.T241= | Silent (SNP) | VAF 4/39 reads (10%) | catalogued as COSV100980695; called by muse, mutect2, varscan2
- OR51B6 | c.231C>A p.P77= | Silent (SNP) | VAF 53/122 reads (43%) | catalogued as COSV100971890; called by muse, mutect2, varscan2
- PCDHA8 | c.1617C>T p.D539= | Silent (SNP) | VAF 23/62 reads (37%) | catalogued as rs782409910, COSV100969991; called by muse, mutect2, varscan2
- PDZRN3 | c.1986C>T p.Y662= | Silent (SNP) | VAF 26/65 reads (40%) | catalogued as rs142044798, COSV104376567; called by muse, mutect2, varscan2
- PIM1 | c.72G>A p.K24= | Silent (SNP) | VAF 24/86 reads (28%) | catalogued as rs768952543, COSV65164988, COSV65166078, COSV65166386; called by muse, varscan2
- PLEKHG1 | c.3297C>G p.L1099= | Silent (SNP) | VAF 19/119 reads (16%) | catalogued as COSV100651823; called by muse, mutect2, varscan2
- PNLIPRP2 | c.1299G>T p.L433= (on ENST00000611850; = p.L434= on NM_005396.5) | Silent (SNP) | VAF 33/137 reads (24%) | catalogued as COSV100077922; called by muse, mutect2, varscan2
- RAN | c.399G>A p.A133= | Silent (SNP) | VAF 17/74 reads (23%) | catalogued as rs769792621, COSV54562173; called by muse, mutect2, varscan2
- SBF2 | c.450C>T p.V150= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as COSV99815433; called by muse, mutect2, varscan2
- SEMA3D | c.855T>C p.V285= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as rs759026992, COSV99407240; called by muse, mutect2, varscan2
- TET2 | c.66T>G p.P22= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as COSV99484356; called by muse, mutect2, varscan2
- TOP2A | c.3852A>G p.P1284= | Silent (SNP) | VAF 71/161 reads (44%) | catalogued as COSV101352314; called by muse, mutect2, varscan2
- XYLT2 | c.291G>A p.R97= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as rs1567805520, COSV99191059; called by muse, mutect2, varscan2
- ZNF236 | c.1431C>T p.N477= | Silent (SNP) | VAF 21/49 reads (43%) | catalogued as rs772659000, COSV99471037; called by muse, mutect2, varscan2
- ZNF276 | c.945C>T p.D315= (on ENST00000443381 / NM_001113525.2; = p.D240= on NM_152287.4) | Silent (SNP) | VAF 22/79 reads (28%) | catalogued as rs771288582, COSV57067796, COSV99235273; called by muse, mutect2
- C7orf65 | n.73G>A | RNA (SNP) | VAF 18/181 reads (10%) | catalogued as rs761837716; called by muse, mutect2, varscan2
- CPLANE1 | c.*5699T>C | 3'UTR (SNP) | VAF 29/144 reads (20%) | catalogued as COSV99951433; called by muse, mutect2, varscan2
- PDE4DIP | c.*57C>T | 3'UTR (SNP) | VAF 8/36 reads (22%) | catalogued as rs587735104, COSV100518165, COSV100521092; called by muse, mutect2, varscan2
- THSD4 | c.1016-70062G>A | Intron (SNP) | VAF 31/99 reads (31%) | catalogued as rs772227943; called by muse, mutect2, varscan2
- TRAPPC9 | chr8:140458347 del GAA | 5'Flank (DEL) | VAF 29/102 reads (28%) | called by mutect2, pindel, varscan2
